Somatic mutation profile of tumor specimen C3N-00547-01 (aliquot CPT0067250006) from CPTAC case C3N-00547, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 60.8 years (22,202 days).
Specimen C3N-00547-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 173c283d-74f7-413d-9977-6bb145cc1f90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00547-71 (Blood Derived Normal), aliquot CPT0067370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75887725-1bf2-4895-96d0-9d7093080233

The open-access MAF lists 803 somatic variants for this specimen: 540 protein-altering or splice-affecting, 159 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 472, Silent 159, Intron 42, Nonsense Mutation 29, RNA 20, Frame Shift Del 15, 3'UTR 14, Splice Site 11, 5'Flank 10, 5'UTR 10, 3'Flank 8, Splice Region 6.

Variants (750 of 803; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 113/307 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.598-1G>T p.X200_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); catalogued as COSV58821045, COSV58823557; called by muse, mutect2, varscan2
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 39/160 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1737G>T p.T579= | Splice Region (SNP) | VAF 15/137 reads (11%) | catalogued as COSV52942823; called by muse, mutect2, varscan2
- ACTL8 | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV100958533; called by muse, mutect2, varscan2
- ADAMTS18 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 80/566 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs760054443, COSV51417690; called by muse, mutect2, varscan2
- ADAMTS5 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53185636; called by muse, mutect2, varscan2
- ADGB | c.3505C>A p.P1169T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381925720; called by muse, mutect2, varscan2
- ADGRL3 | c.3902C>T p.A1301V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770519049; called by muse, mutect2, varscan2
- ADNP2 | c.3188A>T p.H1063L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs763214529; called by muse, mutect2, varscan2
- AHCTF1 | c.6874C>T p.P2292S (on ENST00000366508; = p.P2266S on NM_015446.5) | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752921619; called by muse, mutect2, varscan2
- AMER1 | c.3040G>T p.G1014W | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57654809; called by muse, mutect2, varscan2
- ANKRD30B | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV62810340, COSV62820002; called by muse, mutect2, varscan2
- ANKRD30B | c.3655G>T p.V1219L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100271441; called by muse, mutect2, varscan2
- APOB | c.9749G>T p.G3250V | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51939639; called by muse, mutect2, varscan2
- APOH | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.471); catalogued as COSV99235796; called by muse, mutect2, varscan2
- ARC | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | catalogued as rs769666928; called by muse, mutect2
- ARFGEF2 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 51/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765305868, COSV64210215; called by muse, mutect2, varscan2
- BDNF | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 226/496 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1286344063; called by muse, varscan2
- BFSP1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as rs767136257, COSV64899716; called by muse, mutect2, varscan2
- BRIP1 | c.3571A>G p.I1191V | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs761405340; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- C1QTNF7 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1451465074; called by muse, mutect2, varscan2
- C1orf109 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1167857503; called by muse, mutect2, varscan2
- CA3 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs369670663; called by muse, mutect2
- CATSPERG | c.2402T>C p.L801P | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99286539; called by muse, mutect2, varscan2
- CCDC175 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV55794165; called by muse, mutect2, varscan2
- CD53 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54762800; called by muse, mutect2, varscan2
- CDH23 | c.5653C>T p.R1885C | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs368848049, COSV56473647; ClinVar: uncertain significance; called by muse, mutect2
- CEP250 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs750633022; called by muse, mutect2, varscan2
- CFAP91 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1189036528; called by muse, mutect2, varscan2
- CHI3L1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55140015; called by muse, mutect2, varscan2
- CIC | c.4412G>T p.R1471L | Missense Mutation (SNP) | VAF 235/548 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50550046; called by muse, mutect2, varscan2
- CKMT2 | c.1127T>C p.I376T | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs867641627; called by muse, mutect2, varscan2
- CLCN3 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs767015898; called by muse, mutect2, varscan2
- CLCN7 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 189/643 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV51971581; called by muse, mutect2, varscan2
- CNTNAP2 | c.1745A>G p.E582G | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1554490561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A2 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51960509, COSV51967824; called by muse, mutect2, varscan2
- COL4A2 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs376916470; called by muse, mutect2, varscan2
- COL7A1 | c.4310C>A p.P1437H | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs771635481; called by muse, mutect2, varscan2
- CPT1C | c.1158C>A p.P386= | Splice Region (SNP) | VAF 43/100 reads (43%) | catalogued as COSV99773349; called by muse, varscan2
- CUBN | c.10192G>T p.D3398Y | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV64725412; called by muse, mutect2, varscan2
- CUX2 | c.2066C>A p.S689* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as rs868529535; called by muse, mutect2, varscan2
- DCAF1 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV60041964; called by muse, mutect2, varscan2
- DIDO1 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459198190; called by muse, mutect2
- DNER | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752786455, COSV59161593; called by muse, mutect2, varscan2
- DOCK11 | c.5752G>T p.A1918S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99354492; called by muse, mutect2, varscan2
- DOCK3 | c.1261C>A p.R421S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56505546; called by muse, mutect2, varscan2
- DPT | c.540-1G>T p.X180_splice | Splice Site (SNP) | VAF 63/149 reads (42%) | catalogued as COSV100892177; called by muse, mutect2, varscan2
- DUXA | c.478A>T p.R160* | Nonsense Mutation (SNP) | VAF 20/340 reads (6%) | catalogued as rs1267866887; called by muse, mutect2
- EPHA3 | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV60694432; called by muse, mutect2, varscan2
- EVC2 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as rs761732269, COSV100185420; called by muse, mutect2, varscan2
- FAT3 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53130258; called by muse, mutect2, varscan2
- FGG | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV100271799; called by muse, mutect2, varscan2
- FGG | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100272057; called by muse, mutect2, varscan2
- FLG | c.1596C>A p.H532Q | Missense Mutation (SNP) | VAF 321/772 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV64238470; called by muse, mutect2, varscan2
- FNBP1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs775586594; called by muse, mutect2, varscan2
- GOLGA3 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as rs772049229; called by muse, mutect2, varscan2
- GPR78 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV66763857; called by muse, mutect2, varscan2
- GRID2IP | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.119); catalogued as rs966035901; called by muse, mutect2, varscan2
- GRIN3A | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV62453373; called by muse, mutect2, varscan2
- HHLA1 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV70152113; called by muse, mutect2, varscan2
- HOGA1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as rs1371902226, COSV65706497; called by muse, mutect2
- HOXA11 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 242/751 reads (32%) | catalogued as COSV99135897; called by muse, mutect2, varscan2
- HOXD10 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV50898894; called by muse, mutect2, varscan2
- IDUA | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.392); catalogued as rs1560546903; called by muse, mutect2, varscan2
- IL9R | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs762571736; called by muse, mutect2, varscan2
- ITGA2B | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV52232976; called by muse, mutect2, varscan2
- ITGAM | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV54933686; called by muse, mutect2, varscan2
- ITGB8 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs368140852; called by muse, mutect2, varscan2
- KCNE1 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 59/206 reads (29%) | catalogued as CM970799; called by muse, mutect2, varscan2
- KIAA1755 | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs755400632, COSV54080627, COSV99641408, COSV99642774; called by muse, mutect2, varscan2
- KIF21A | c.2473C>T p.R825C (on ENST00000361418 / NM_001378440.1; = p.R812C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/545 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs751352937; called by muse, mutect2, varscan2
- KLK10 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV59397869; called by muse, mutect2, varscan2
- KPTN | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs1168080673; called by muse, mutect2
- KRTAP21-2 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV61684771; called by muse, mutect2, varscan2
- KRTAP8-1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV61597926; called by muse, mutect2, varscan2
- LCT | c.2104A>G p.S702G | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs1296883178; called by muse, mutect2, varscan2
- LRP12 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs935481003; called by muse, mutect2, varscan2
- LRRN2 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65784203; called by muse, mutect2, varscan2
- MANBA | c.2261C>T p.S754L (on ENST00000642252; = p.S708L on NM_005908.4) | Missense Mutation (SNP) | VAF 123/267 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56965451; called by muse, mutect2, varscan2
- MAP10 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 91/493 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.075); catalogued as COSV69363148; called by muse, mutect2, varscan2
- MON1B | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.957); catalogued as rs781298641, COSV99941649; called by muse, mutect2, varscan2
- MROH9 | c.1091A>C p.K364T | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757325841; called by muse, mutect2, varscan2
- MYLIP | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62766504; called by muse, mutect2, varscan2
- MYO1D | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV57831704; called by muse, mutect2, varscan2
- NEB | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs757784515; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NEIL3 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756626713, COSV52810663; called by muse, mutect2, varscan2
- NEUROD1 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 103/439 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54548593; called by muse, mutect2, varscan2
- NINL | c.2755G>T p.V919F | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1185520159; called by muse, mutect2, varscan2
- NLRP8 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1314344900; called by muse, mutect2, varscan2
- NMUR1 | c.1008C>A p.H336Q | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59404935; called by muse, mutect2, varscan2
- NOTCH1 | c.3503C>T p.S1168F | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs375190395, COSV104374233; called by muse, mutect2, varscan2
- NRK | c.2960C>A p.A987E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV99687514; called by muse, mutect2, varscan2
- NRXN3 | c.358A>T p.T120S (on ENST00000557594 / NM_001272020.2; = p.T752S on NM_004796.6) | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV55326648; called by muse, mutect2, varscan2
- NWD2 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs774664515; called by muse, mutect2, varscan2
- OR10T2 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1312777078, COSV57782742; called by muse, mutect2
- OR11H4 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100197651; called by muse, mutect2, varscan2
- OR2M3 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs765319846; called by muse, mutect2, varscan2
- OR2M3 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs1162232105, COSV101513497; called by muse, mutect2, varscan2
- OR8J1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV57317045; called by muse, mutect2, varscan2
- OTUD7A | c.1303G>T p.E435* (on ENST00000307050 / NM_001382637.1; = p.E428* on NM_130901.3) | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100193394; called by muse, mutect2
- P2RY14 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 166/277 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV56396541; called by muse, mutect2, varscan2
- PAPPA | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs144678054, COSV60284915; called by muse, mutect2, varscan2
- PDE10A | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV63095844; called by muse, varscan2
- PDZRN3 | c.2975G>C p.R992P | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55200778; called by muse, mutect2, varscan2
- PELI2 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); catalogued as COSV50717627; called by muse, mutect2, varscan2
- PHTF2 | c.1328C>G p.P443R (on ENST00000248550 / NM_001366089.1; = p.P405R on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.889); catalogued as COSV99301503; called by muse, mutect2, varscan2
- PLAC1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 187/290 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV63656850; called by muse, mutect2, varscan2
- PLCE1 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99594370; called by muse, mutect2, varscan2
- POTEE | c.2195del p.P732Lfs*12 | Frame Shift Del (DEL) | VAF 55/274 reads (20%) | catalogued as COSV100389021; called by mutect2, pindel, varscan2
- PREX2 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs779206847; called by muse, mutect2
- PTPN13 | c.5338G>C p.D1780H (on ENST00000411767 / NM_080683.3; = p.D1761H on NM_006264.3) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV57415885; called by muse, mutect2
- PTPRD | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.216); catalogued as COSV61957209; called by muse, mutect2, varscan2
- PTPRD | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61954112, COSV61963091; called by muse, mutect2, varscan2
- PTPRN2 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs954741129; called by muse, mutect2, varscan2
- PUS7 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100708389; called by muse, mutect2, varscan2
- PXDNL | c.3031C>A p.H1011N | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62498004; called by muse, mutect2, varscan2
- RAB19 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.436); catalogued as COSV52046518; called by muse, mutect2, varscan2
- RAC2 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 85/392 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV50774786; called by muse, mutect2, varscan2
- RERG | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs771987061; called by muse, mutect2, varscan2
- RHOXF1 | c.96C>G p.S32R | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1377162159, COSV54295540; called by muse, mutect2, varscan2
- RPS6KC1 | c.2024A>T p.D675V | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1275723734, COSV65302058; called by muse, mutect2, varscan2
- RPTOR | c.990G>C p.R330= | Splice Region (SNP) | VAF 31/239 reads (13%) | catalogued as rs1227574862; called by muse, mutect2, varscan2
- RTF2 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV99196467; called by muse, mutect2, varscan2
- RYR1 | c.3161C>A p.P1054H | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62103433; called by muse, mutect2, varscan2
- SAFB2 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs764134146, COSV99385691; called by muse, mutect2, varscan2
- SALL1 | c.2890C>A p.P964T | Missense Mutation (SNP) | VAF 44/762 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51762964; called by muse, mutect2
- SCN3A | c.1180C>A p.R394S | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51822759; called by muse, varscan2
- SEMA3C | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV54841386; called by muse, mutect2
- SERPINB11 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66957855; called by muse, varscan2
- SERPINB6 | c.808G>T p.E270* (on ENST00000612421 / NM_001271823.2; = p.E251* on NM_004568.6) | Nonsense Mutation (SNP) | VAF 68/183 reads (37%) | catalogued as COSV59568305; called by muse, mutect2, varscan2
- SLITRK3 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 164/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53853357, COSV99579300; called by muse, mutect2, varscan2
- SNX29 | c.2125T>A p.Y709N | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.44); catalogued as COSV60066643; called by muse, mutect2, varscan2
- SPATA31A3 | c.2076G>T p.K692N | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs1213094410; called by muse, mutect2, varscan2
- SPTLC2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.038); catalogued as rs1258728755; called by muse, mutect2, varscan2
- SRGAP2 | c.968G>A p.S323N (on ENST00000624873 / NM_001170637.4; = p.S324N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1553355584; called by muse, mutect2, varscan2
- SSC5D | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1171615519; called by muse, mutect2, varscan2
- ST8SIA6 | c.578del p.G193Efs*3 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as COSV66465615; called by mutect2, pindel, varscan2
- SYNE1 | c.1009G>A p.A337T (on ENST00000367255 / NM_182961.4; = p.A344T on NM_033071.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs112283206; called by muse, mutect2, varscan2
- TAMALIN | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53336676; called by muse, mutect2, varscan2
- TAS2R41 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV68765918; called by muse, mutect2, varscan2
- TBX18 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as rs753798713; called by muse, mutect2, varscan2
- TFDP2 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs771209446; called by muse, mutect2, varscan2
- TLR4 | c.1238C>A p.T413N (on ENST00000355622 / NM_138554.5; = p.T373N on NM_003266.4) | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.377); catalogued as COSV62923386; called by muse, mutect2, varscan2
- TMEM132D | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 68/211 reads (32%) | catalogued as COSV70614999; called by muse, mutect2, varscan2
- TNR | c.1507+1G>T p.X503_splice | Splice Site (SNP) | VAF 22/113 reads (19%) | catalogued as COSV54915416; called by muse, mutect2, varscan2
- TRAPPC12 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV60847181, COSV60848898; called by muse, mutect2
- TRIM3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV61984853; called by muse, mutect2, varscan2
- TRIM51 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs367940835, COSV55267170; called by muse, varscan2
- TRIM63 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs1204604066; called by muse, mutect2, varscan2
- TRIM9 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV53623193; called by muse, mutect2, varscan2
- TSHZ3 | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1257000724; called by muse, mutect2, varscan2
- TTN | c.48248G>T p.G16083V (on ENST00000591111; = p.G8659V on NM_003319.4) | Missense Mutation (SNP) | VAF 84/292 reads (29%) | PolyPhen probably damaging (0.993); catalogued as rs1385094780, COSV60019251; called by muse, mutect2, varscan2
- TUBB8 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV59115345; called by muse, varscan2
- USH2A | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1334472814; called by muse, mutect2
- VDAC1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 191/356 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99527229; called by muse, mutect2, varscan2
- VN1R5 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs754304296; called by muse, mutect2, varscan2
- VPS13B | c.7848del p.W2616Cfs*9 | Frame Shift Del (DEL) | VAF 171/410 reads (42%) | catalogued as COSV62154722; called by mutect2, pindel, varscan2
- ZEB2 | c.2480C>A p.P827H | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV57963236; called by muse, mutect2, varscan2
- ZNF106 | c.1753G>C p.A585P | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs376128302; called by muse, mutect2, varscan2
- ZNF208 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs762166538; called by muse, mutect2, varscan2
- ZNF578 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV69737193; called by muse, varscan2
- ZNF619 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV59031705; called by muse, mutect2, varscan2
- ZNF746 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV61407664; called by muse, mutect2
- ABCA1 | c.1908G>T p.M636I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2
- ABCA1 | c.1907T>A p.M636K | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2
- ABCA12 | c.482T>A p.L161H | Missense Mutation (SNP) | VAF 134/383 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ABCB4 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ABCC10 | c.928G>T p.V310L (on ENST00000372530 / NM_001198934.2; = p.V267L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAN | c.7481C>G p.A2494G (on ENST00000560601 / NM_001369268.1; = p.A2456G on NM_013227.3) | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTL7B | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADA2 | c.1528A>G p.T510A (on ENST00000262607; = p.T269A on NM_177405.3) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.4384C>G p.P1462A (on ENST00000506720 / NM_001322402.2; = p.P1351A on NM_015236.6) | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- AGXT2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AHNAK | c.7795G>T p.V2599F | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.8155G>A p.G2719S | Missense Mutation (SNP) | VAF 127/384 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AKR1B1 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- AL592490.1 | c.1548T>G p.H516Q | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ALDOB | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 90/446 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- AMER3 | c.2440G>T p.G814C | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ANKRD30A | c.349C>A p.H117N (on ENST00000611781; = p.H61N on NM_052997.2) | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, varscan2
- ANKRD30A | c.3608C>T p.A1203V (on ENST00000611781; = p.A1147V on NM_052997.2) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ANKRD30BL | c.18del p.A7Pfs*27 | Frame Shift Del (DEL) | VAF 50/186 reads (27%) | called by pindel, varscan2
- AP002748.5 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 36/685 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); called by muse, mutect2
- AP4B1 | c.2003C>G p.T668S | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- APBA2 | c.1604C>G p.P535R | Missense Mutation (SNP) | VAF 106/331 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- APOL4 | c.679C>A p.P227T (on ENST00000352371 / NM_145660.2; = p.P224T on NM_030643.4) | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- AQP12B | c.123+2T>A p.X41_splice (on ENST00000621682; = p.V42E on NM_001102467.2) | Splice Site (SNP) | VAF 182/858 reads (21%) | called by muse, mutect2, varscan2
- AQP6 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ARAP2 | c.4936G>T p.G1646W | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ARID1A | c.5287del p.E1763Kfs*7 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel
- ARID2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB15 | c.1665C>A p.C555* | Nonsense Mutation (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- ASPG | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ASXL3 | c.6406C>A p.Q2136K | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ATP4A | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 85/484 reads (18%) | called by muse, mutect2, varscan2
- ATP9B | c.2186A>G p.E729G | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GALT2 | c.662_667del p.L221_T223delinsS | In Frame Del (DEL) | VAF 36/186 reads (19%) | called by mutect2, pindel, varscan2
- BDNF | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 72/550 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- BRWD3 | c.3263A>T p.H1088L | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- BRWD3 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 148/254 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C16orf82 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- C19orf44 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); called by muse, mutect2
- C2CD4C | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.3187G>T p.D1063Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CACNA1S | c.881G>T p.W294L | Missense Mutation (SNP) | VAF 153/677 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CASP8AP2 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASS4 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CCDC144A | c.2599A>T p.I867L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDC6 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDH23 | c.5074A>G p.I1692V | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- CDK19 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CFAP46 | c.6410T>A p.V2137E | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CFAP61 | c.2422T>G p.C808G | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- CHL1 | c.3073G>T p.V1025L (on ENST00000397491 / NM_001253387.1; = p.V1041L on NM_006614.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, varscan2
- CHUK | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CIAO1 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CKB | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CLDN17 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.1610del p.P537Qfs*35 | Frame Shift Del (DEL) | VAF 61/162 reads (38%) | called by mutect2, pindel, varscan2
- CNTN6 | c.1276del p.D426Ifs*55 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | called by mutect2, pindel, varscan2
- COL11A1 | c.2795C>A p.P932Q | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL20A1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL21A1 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- COL5A2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COQ8B | c.727A>T p.I243L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CPT1C | c.140G>C p.W47S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPXM2 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CRACR2A | c.1459T>C p.F487L | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRACR2A | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREB3L3 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 239/495 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- CREG1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CRISPLD2 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRMP1 | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- CROCC | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CSMD3 | c.5659G>C p.G1887R (on ENST00000297405 / NM_001363185.1; = p.G1783R on NM_052900.3) | Missense Mutation (SNP) | VAF 139/289 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CSMD3 | c.1207A>C p.N403H | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CUBN | c.10191A>C p.R3397S | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP26A1 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CYP4F22 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 152/321 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CYTH4 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DACH2 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF10 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- DCDC1 | c.3667G>T p.V1223L (on ENST00000597505 / NM_001367979.1; = p.V330L on NM_020869.3) | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DCDC2C | c.844A>T p.R282W | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, varscan2
- DCHS1 | c.5608G>T p.A1870S | Missense Mutation (SNP) | VAF 165/316 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DCHS1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DDHD2 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 72/198 reads (36%) | called by muse, mutect2, varscan2
- DENND1A | c.2012C>A p.P671H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- DGAT2L6 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 118/196 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- DGKB | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 80/299 reads (27%) | called by muse, mutect2, varscan2
- DIAPH2 | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- DISP3 | c.2885C>A p.P962H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DMWD | c.1793G>T p.C598F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DNAI2 | c.1277C>A p.T426N | Missense Mutation (SNP) | VAF 128/457 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DUOX2 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 86/450 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DYNC1H1 | c.9106G>A p.G3036R | Missense Mutation (SNP) | VAF 225/635 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ECH1 | c.974_976del p.F325del | In Frame Del (DEL) | VAF 106/251 reads (42%) | called by mutect2, pindel, varscan2
- ECT2L | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EGLN2 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2
- EIF2B5 | c.1845G>C p.Q615H (on ENST00000647909; = p.Q607H on NM_003907.3) | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- EPB41L4B | c.1386G>T p.W462C | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ERN2 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EVX1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXOC3L2 | c.1645T>A p.S549T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EXOC6B | c.1053dup p.V352Cfs*3 | Frame Shift Ins (INS) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- EXTL3 | c.1236G>T p.W412C | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYS | c.4014T>A p.S1338R | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM135B | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM163A | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM178B | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FAM184B | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- FAM53A | c.1067G>T p.R356M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FAM98A | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAR1 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, varscan2
- FCGR2A | c.115C>A p.P39T (on ENST00000271450 / NM_001136219.3; = p.P38T on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FCN1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FER1L6 | c.3191G>T p.C1064F | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FGF14 | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FKBPL | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); called by muse, mutect2
- FLNC | c.5668+1G>T p.X1890_splice | Splice Site (SNP) | VAF 121/401 reads (30%) | called by muse, mutect2, varscan2
- FLRT2 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.112); called by muse, mutect2
- FRAS1 | c.8481C>A p.D2827E | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FRAS1 | c.8482C>A p.L2828I | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- FREM3 | c.2456C>A p.T819K | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- FRYL | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- GABRA1 | c.931dup p.T311Nfs*20 | Frame Shift Ins (INS) | VAF 176/400 reads (44%) | called by mutect2, pindel, varscan2
- GABRG1 | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG3 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRR1 | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GALNT17 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GALNT2 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, varscan2
- GEM | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA1 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 60/715 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GMEB2 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GMIP | c.2485C>G p.Q829E | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRASP2 | c.857A>T p.D286V | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GRIK1 | c.1724C>A p.S575Y | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIP1 | c.1197T>A p.P399= | Splice Region (SNP) | VAF 54/372 reads (15%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4733del p.G1578Afs*16 | Frame Shift Del (DEL) | VAF 86/339 reads (25%) | called by mutect2, pindel, varscan2
- HAPLN2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HAVCR2 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HEATR1 | c.3293del p.G1098Efs*31 | Frame Shift Del (DEL) | VAF 27/175 reads (15%) | called by mutect2, pindel
- HECW1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.6796G>C p.V2266L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC2 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HINT1 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2
- HMCN2 | c.12220G>T p.G4074C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HNF4A | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- HRH2 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 210/399 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- HSD11B1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HUWE1 | c.7772A>T p.Q2591L | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IFNAR1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHD | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-9 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IL19 | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL27 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- IQGAP2 | c.3001A>T p.N1001Y | Missense Mutation (SNP) | VAF 113/195 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ISOC1 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ITGA2 | c.1312+1G>T p.X438_splice | Splice Site (SNP) | VAF 192/458 reads (42%) | called by mutect2, varscan2
- ITGAX | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH5 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6B | c.4148A>T p.D1383V | Missense Mutation (SNP) | VAF 252/660 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, varscan2
- KATNIP | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | called by muse, varscan2
- KBTBD11 | c.1414A>T p.K472* | Nonsense Mutation (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- KBTBD13 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KCNA6 | c.1531A>G p.S511G | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KCNH8 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMA1 | c.3055G>T p.D1019Y (on ENST00000286628 / NM_001161352.2; = p.D961Y on NM_002247.4) | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNQ2 | c.2418C>A p.S806R (on ENST00000359125 / NM_172107.4; = p.S778R on NM_004518.6) | Missense Mutation (SNP) | VAF 61/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ2 | c.1469G>T p.S490I (on ENST00000359125 / NM_172107.4; = p.S462I on NM_004518.6) | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- KCNT2 | c.3277A>G p.I1093V | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCP | c.1342G>A p.A448T (on ENST00000620378; = p.A505T on NM_001366122.1) | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- KHDC1 | c.560A>T p.D187V (on ENST00000370384 / NM_001251874.2; = p.D114V on NM_030568.5) | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KIAA1109 | c.2224C>A p.L742I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF13B | c.4994G>A p.G1665E | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KIF5C | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- KIF5C | c.1873del p.E625Sfs*19 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KLHL11 | c.1585del p.T529Qfs*43 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | called by pindel, varscan2
- KRT15 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LAMA1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 105/375 reads (28%) | called by muse, mutect2, varscan2
- LAMC2 | c.954-1G>T p.X318_splice | Splice Site (SNP) | VAF 156/396 reads (39%) | called by muse, mutect2, varscan2
- LARS2 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- LCT | c.1626G>T p.E542D | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- LHFPL3 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LIPK | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LLPH | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); called by muse, varscan2
- LPO | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- LRP2 | c.10613G>T p.C3538F | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC4C | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 115/218 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ1 | c.558A>T p.K186N | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- LRRK2 | c.376A>T p.N126Y | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LYST | c.6567T>G p.D2189E | Missense Mutation (SNP) | VAF 350/785 reads (45%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAGEB6 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAP1LC3C | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- MAP3K20 | c.540T>G p.S180R | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MASP1 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- MC3R | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2
- MMP8 | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MRGPRX1 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MS4A14 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 162/357 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MTERF1 | c.270del p.K91Nfs*10 | Frame Shift Del (DEL) | VAF 27/233 reads (12%) | called by mutect2, pindel, varscan2
- MUC16 | c.26998C>A p.L9000M | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MUC16 | c.1199G>T p.S400I | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, varscan2
- MUC5AC | c.15680C>G p.P5227R | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH4 | c.4486C>A p.L1496M | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MYLIP | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MYO18B | c.3637G>C p.G1213R | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYO18B | c.5602C>A p.L1868M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MYO3B | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO9B | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- NCALD | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NELL2 | c.1924C>A p.H642N | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NEU4 | c.394G>T p.A132S (on ENST00000391969 / NM_001167602.3; = p.A144S on NM_080741.4) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NIN | c.4007A>T p.Q1336L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN1 | c.1716A>T p.E572D | Missense Mutation (SNP) | VAF 105/180 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP2 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 238/646 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- NLRP3 | c.1534T>A p.C512S | Missense Mutation (SNP) | VAF 112/443 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NLRP7 | c.2908G>C p.A970P (on ENST00000340844 / NM_206828.3; = p.A999P on NM_139176.3) | Missense Mutation (SNP) | VAF 189/559 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP7 | c.2471C>A p.S824* (on ENST00000340844 / NM_206828.3; = p.S796* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 60/356 reads (17%) | called by muse, mutect2, varscan2
- NPAP1 | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NPC1L1 | c.4009A>T p.S1337C | Missense Mutation (SNP) | VAF 283/806 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- NTRK1 | c.779G>T p.R260M | Missense Mutation (SNP) | VAF 86/465 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- NYNRIN | c.362del p.G121Afs*3 | Frame Shift Del (DEL) | VAF 60/276 reads (22%) | called by mutect2, pindel, varscan2
- OR10J3 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 152/371 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR11H2 | c.948A>T p.*316Yext*? (on ENST00000556246; = p.*327Yext*? on NM_001197287.1) | Nonstop Mutation (SNP) | VAF 53/394 reads (13%) | called by muse, varscan2
- OR1Q1 | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, varscan2
- OR2B2 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- OR2T35 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 62/537 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OR4C15 | c.543G>T p.K181N (on ENST00000314644; = p.K127N on NM_001001920.2) | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR51B2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR6V1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- OTOG | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- OTOG | c.5404C>A p.L1802I | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OTUD6A | c.451C>A p.H151N | Missense Mutation (SNP) | VAF 119/189 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PALD1 | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PANX1 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB10 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 162/313 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCLO | c.10484G>C p.G3495A | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PDGFRA | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKDREJ | c.3609G>A p.W1203* | Nonsense Mutation (SNP) | VAF 57/202 reads (28%) | called by muse, mutect2, varscan2
- PKHD1 | c.10543A>G p.I3515V | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PLA2G12B | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCE1 | c.3116G>T p.G1039V | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PLEKHA2 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PLEKHA6 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PLEKHM1 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PM20D2 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PNPLA1 | c.1556C>A p.P519Q (on ENST00000394571 / NM_001374623.1; = p.P424Q on NM_173676.2) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLL | c.1364-6G>T | Splice Region (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- POLR1C | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- POTEI | c.2878G>T p.A960S | Missense Mutation (SNP) | VAF 138/516 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- PPP1R1A | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM12 | c.263T>A p.V88E | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRMT3 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2
- PRPS1L1 | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PRR23B | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRUNE2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- PSAPL1 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- PTCD1 | c.1402A>C p.I468L | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN23 | c.2010G>C p.K670N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PTPN4 | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PTPN5 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2
- PTPN5 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2
- PTPRB | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PTPRZ1 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PXDN | c.2404C>A p.L802M | Missense Mutation (SNP) | VAF 256/542 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- QARS1 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB11FIP1 | c.3808C>T p.L1270F (on ENST00000330843 / NM_001002814.3; = p.L636F on NM_025151.5) | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD18 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- RADX | c.2071G>T p.G691C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- RADX | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- RAPGEF2 | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA3 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 130/255 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RBM15 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- RBM20 | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RCAN2 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, varscan2
- RCAN2 | c.56T>A p.V19D | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, varscan2
- RFX6 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 47/195 reads (24%) | called by muse, mutect2, varscan2
- RHCG | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS1 | c.1816A>T p.T606S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RINT1 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- RNF144A | c.748-2A>T p.X250_splice | Splice Site (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- RNF180 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- RP1 | c.6163A>T p.S2055C | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RPA1 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- RPS6KL1 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RRP15 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 62/265 reads (23%) | called by muse, mutect2, varscan2
- RTTN | c.4972G>T p.V1658F | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- RYR2 | c.7053del p.I2353Sfs*37 | Frame Shift Del (DEL) | VAF 30/187 reads (16%) | called by mutect2, pindel
- RYR2 | c.10168C>G p.P3390A | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SALL3 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD1 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMM50 | c.1198G>C p.G400R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN5A | c.3118G>T p.G1040W | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SEMA6D | c.3023A>T p.K1008M (on ENST00000316364 / NM_153618.2; = p.K946M on NM_020858.2) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SIGLEC5 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SLC12A5 | c.1428dup p.G477Wfs*5 (on ENST00000454036 / NM_001134771.2; = p.G454Wfs*5 on NM_020708.5) | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- SLC17A1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC25A32 | c.426G>C p.W142C | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35F6 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC36A2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 191/363 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SLC4A1 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC6A15 | c.2053A>T p.M685L | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A5 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A13 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 142/283 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SLC9A1 | c.1428G>T p.M476I | Missense Mutation (SNP) | VAF 88/402 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC9A4 | c.945A>T p.L315F | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1B3 | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLFN11 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMARCD2 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SMOC1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 58/528 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMURF2 | c.1749G>A p.R583= | Splice Region (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- SNX1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SNX32 | c.1204dup p.E402Gfs*5 | Frame Shift Ins (INS) | VAF 31/254 reads (12%) | called by mutect2, pindel, varscan2
- SNX5 | c.149A>C p.H50P | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SOX6 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SPATA31A6 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SPATA31D1 | c.2108C>A p.P703H | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ST3GAL3 | c.725T>A p.V242D (on ENST00000361392 / NM_174964.4; = p.V227D on NM_006279.5) | Missense Mutation (SNP) | VAF 273/621 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST6GAL2 | c.883A>T p.S295C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | PolyPhen benign (0.322); called by muse, mutect2, varscan2
- STAB2 | c.2303del p.E768Gfs*36 | Frame Shift Del (DEL) | VAF 86/303 reads (28%) | called by mutect2, pindel, varscan2
- STIM2 | c.1996C>A p.P666T | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SUGP2 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 102/185 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SYNRG | c.2276G>C p.G759A | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SZT2 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SZT2 | c.3028C>A p.L1010I | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TANC1 | c.365-3_365-2delinsG p.X122_splice | Splice Site (DEL) | VAF 19/52 reads (37%) | called by pindel, varscan2*
- TENT4A | c.1907G>T p.S636I | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.706); called by muse, varscan2
- TEP1 | c.3425G>T p.S1142I | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TEX49 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TGM6 | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 100/714 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- THRB | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 47/461 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- TIMELESS | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TINAG | c.1112A>T p.N371I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TLDC2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- TLR9 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM265 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- TMEM71 | c.743C>T p.A248V (on ENST00000523829 / NM_001382398.1; = p.A229V on NM_144649.3) | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.586); called by muse, mutect2
- TMF1 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- TMPRSS11A | c.1095T>A p.D365E | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS11B | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMPRSS11E | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- TNS3 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM27 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- TRIM51 | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRMT12 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- TRPM5 | c.1111G>T p.G371W | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSEN54 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TTN | c.85778T>C p.F28593S (on ENST00000591111; = p.F21169S on NM_003319.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- UBAP1L | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- UHRF1BP1L | c.2450T>A p.M817K | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UNC5C | c.2560A>T p.S854C | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- UNCX | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- UROC1 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 239/557 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- USH2A | c.4140C>G p.I1380M | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- USP34 | c.5434-2A>T p.X1812_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | called by muse, varscan2
- UTF1 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.7321A>T p.S2441C | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- WSCD1 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); called by muse, varscan2
- XIRP1 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- XIRP2 | c.437C>G p.T146R (on ENST00000628543; = p.T321R on NM_152381.6) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, varscan2
- ZBTB34 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZC3H7A | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFHX4 | c.2996T>A p.L999Q | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.8431A>T p.S2811C | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF415 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ZNF419 | c.161A>T p.N54I | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF470 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF519 | c.1076G>T p.R359M | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF521 | c.1190C>A p.S397* | Nonsense Mutation (SNP) | VAF 85/263 reads (32%) | called by mutect2, varscan2
- ZNF676 | c.139G>T p.A47S (on ENST00000650058; = p.A15S on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF727 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF729 | c.2273A>T p.H758L | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF799 | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSCAN16 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZSCAN29 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ABLIM1 | c.1353G>T p.T451= | Silent (SNP) | VAF 64/180 reads (36%) | called by muse, mutect2, varscan2
- ACACB | c.657G>T p.P219= | Silent (SNP) | VAF 116/306 reads (38%) | called by muse, mutect2, varscan2
- ACSL4 | c.657C>T p.I219= (on ENST00000340800 / NM_022977.2; = p.I178= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- ACTA1 | c.342C>T p.P114= | Silent (SNP) | VAF 194/444 reads (44%) | called by muse, mutect2, varscan2
- ADGRL3 | c.970C>A p.R324= (on ENST00000506720 / NM_001322402.2; = p.R256= on NM_015236.6) | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- AGRN | c.5646C>T p.T1882= | Silent (SNP) | VAF 82/420 reads (20%) | catalogued as rs577578019; called by muse, mutect2, varscan2
- AHNAK2 | c.5325G>T p.A1775= | Silent (SNP) | VAF 137/653 reads (21%) | called by muse, mutect2, varscan2
- ANKRD33 | c.375C>A p.P125= (on ENST00000340970 / NM_001304459.2; = p.P250= on NM_182608.4) | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- ATAD3B | c.606C>G p.L202= (on ENST00000308647; = p.L308= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as COSV58019584; called by muse, mutect2
- BTD | c.852A>T p.P284= | Silent (SNP) | VAF 62/283 reads (22%) | called by muse, mutect2, varscan2
- C1orf167 | c.3633C>A p.A1211= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- CACNA1A | c.1020C>T p.F340= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as COSV100802082; called by muse, mutect2, varscan2
- CACNB2 | c.309C>A p.A103= (on ENST00000324631 / NM_201596.3; = p.A48= on NM_000724.4) | Silent (SNP) | VAF 167/520 reads (32%) | called by muse, mutect2, varscan2
- CASR | c.2994A>T p.V998= (on ENST00000490131; = p.V1075= on NM_000388.4) | Silent (SNP) | VAF 185/350 reads (53%) | called by muse, mutect2, varscan2
- CCDC74B | c.786G>T p.L262= | Silent (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
- CD4 | c.876T>A p.A292= | Silent (SNP) | VAF 50/236 reads (21%) | called by muse, mutect2, varscan2
- CD86 | c.600C>A p.S200= (on ENST00000330540 / NM_175862.5; = p.S194= on NM_006889.4) | Silent (SNP) | VAF 27/259 reads (10%) | called by muse, mutect2, varscan2
- CDH10 | c.2001C>A p.T667= | Silent (SNP) | VAF 108/462 reads (23%) | catalogued as COSV52579918; called by muse, mutect2, varscan2
- CHMP2B | c.198G>T p.V66= | Silent (SNP) | VAF 50/273 reads (18%) | called by muse, mutect2, varscan2
- CLSTN1 | c.1590C>T p.H530= (on ENST00000377298 / NM_001009566.3; = p.H520= on NM_014944.4) | Silent (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- CLTA | c.132G>T p.A44= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2484G>T p.G828= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- COG3 | c.1752A>G p.A584= | Silent (SNP) | VAF 31/146 reads (21%) | called by muse, mutect2, varscan2
- COL11A2 | c.1308C>A p.L436= (on ENST00000341947 / NM_080680.3; = p.L329= on NM_080679.2) | Silent (SNP) | VAF 36/264 reads (14%) | catalogued as rs182684593; called by muse, mutect2, varscan2
- COX4I1 | c.408G>A p.E136= | Silent (SNP) | VAF 105/270 reads (39%) | catalogued as rs768199794; called by muse, mutect2, varscan2
- CPS1 | c.2550T>A p.R850= | Silent (SNP) | VAF 68/482 reads (14%) | catalogued as COSV51828076; called by muse, mutect2, varscan2
- CREB3L3 | c.960A>T p.T320= | Silent (SNP) | VAF 237/492 reads (48%) | called by muse, mutect2
- CSMD3 | c.8328A>T p.S2776= (on ENST00000297405 / NM_001363185.1; = p.S2607= on NM_052900.3) | Silent (SNP) | VAF 127/376 reads (34%) | called by muse, mutect2, varscan2
- CTSG | c.762C>A p.P254= | Silent (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2
- CYP26A1 | c.936G>T p.L312= | Silent (SNP) | VAF 56/185 reads (30%) | called by muse, mutect2, varscan2
- DEFB123 | c.63C>A p.G21= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, varscan2
- DLL1 | c.945T>A p.S315= | Silent (SNP) | VAF 60/302 reads (20%) | called by muse, mutect2, varscan2
- DMRT3 | c.918G>A p.A306= | Silent (SNP) | VAF 21/222 reads (9%) | catalogued as COSV51903760; called by muse, mutect2
- DNPEP | c.984G>T p.L328= | Silent (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- DUOX2 | c.2445G>T p.L815= | Silent (SNP) | VAF 84/438 reads (19%) | called by muse, mutect2
- DUSP2 | c.540G>T p.L180= | Silent (SNP) | VAF 46/193 reads (24%) | called by muse, mutect2, varscan2
- EDC4 | c.2593C>T p.L865= | Silent (SNP) | VAF 40/292 reads (14%) | called by muse, mutect2, varscan2
- EFL1 | c.2610G>C p.V870= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- EHMT1 | c.3798G>T p.S1266= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV101135013; called by muse, mutect2, varscan2
- EPHA4 | c.291G>C p.V97= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- EXT2 | c.1524A>C p.P508= (on ENST00000343631; = p.P541= on NM_000401.3) | Silent (SNP) | VAF 65/329 reads (20%) | called by muse, mutect2, varscan2
- EYA4 | c.996C>T p.F332= (on ENST00000531901 / NM_001301013.1; = p.F326= on NM_004100.5) | Silent (SNP) | VAF 41/286 reads (14%) | catalogued as rs773095472, CM138393, COSV62049831; called by muse, mutect2, varscan2
- FAT2 | c.3798G>T p.L1266= | Silent (SNP) | VAF 167/312 reads (54%) | called by muse, mutect2, varscan2
- FILIP1L | c.474G>A p.L158= | Silent (SNP) | VAF 89/223 reads (40%) | catalogued as COSV100496682; called by muse, mutect2, varscan2
- GALT | c.441C>T p.I147= | Silent (SNP) | VAF 85/446 reads (19%) | catalogued as COSV66593149; called by muse, mutect2, varscan2
- GAS2L3 | c.1842C>T p.S614= | Silent (SNP) | VAF 57/306 reads (19%) | called by muse, mutect2, varscan2
- GCNT3 | c.297A>T p.T99= | Silent (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- GOLGA5 | c.333G>A p.V111= | Silent (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- GPR137 | c.54G>A p.L18= | Silent (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- GPR25 | c.393G>C p.A131= | Silent (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- IGHA1 | c.9G>T p.P3= | Silent (SNP) | VAF 33/98 reads (34%) | called by muse, varscan2
- IL20RB | c.558G>T p.G186= | Silent (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- IL25 | c.507G>A p.V169= | Silent (SNP) | VAF 64/175 reads (37%) | called by muse, mutect2, varscan2
- ITGB5 | c.723G>C p.R241= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- ITPR3 | c.1164G>T p.R388= | Silent (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- KCNC2 | c.360C>T p.T120= | Silent (SNP) | VAF 61/376 reads (16%) | catalogued as COSV100129516; called by muse, mutect2, varscan2
- KCNG1 | c.870G>A p.A290= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as rs1473334516, COSV65367893; called by muse, mutect2, varscan2
- KCNIP3 | c.165A>T p.T55= | Silent (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- KCNJ14 | c.501G>C p.V167= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- KHSRP | c.1512A>T p.P504= | Silent (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- KLK10 | c.381C>A p.P127= | Silent (SNP) | VAF 53/168 reads (32%) | called by muse, mutect2, varscan2
- LGALS9B | c.730C>T p.L244= (on ENST00000423676 / NM_001367292.1; = p.L243= on NM_001042685.2) | Silent (SNP) | VAF 67/252 reads (27%) | called by muse, mutect2, varscan2
- LPA | c.4635C>A p.G1545= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, varscan2
- LRGUK | c.183G>T p.L61= | Silent (SNP) | VAF 35/268 reads (13%) | called by muse, mutect2, varscan2
- LRRC66 | c.2457G>T p.P819= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV58634251; called by muse, mutect2, varscan2
- LRRK1 | c.381A>T p.A127= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- LRRTM4 | c.924G>A p.L308= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV101297756; called by muse, mutect2, varscan2
- MAP3K15 | c.1020G>A p.E340= | Silent (SNP) | VAF 42/67 reads (63%) | called by muse, mutect2, varscan2
- METTL11B | c.630T>C p.D210= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- MFGE8 | c.639C>T p.H213= | Silent (SNP) | VAF 49/350 reads (14%) | called by muse, mutect2, varscan2
- MIA2 | c.945A>T p.T315= | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- MN1 | c.783G>A p.A261= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- MUC5B | c.8916C>A p.P2972= | Silent (SNP) | VAF 139/347 reads (40%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3522C>A p.A1174= | Silent (SNP) | VAF 63/157 reads (40%) | called by muse, mutect2, varscan2
- MYH2 | c.126G>A p.E42= | Silent (SNP) | VAF 64/335 reads (19%) | catalogued as COSV99819232; called by muse, mutect2, varscan2
- NCKAP5 | c.2829C>A p.P943= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- NKX2-6 | c.294C>A p.A98= | Silent (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- NLRP8 | c.213C>T p.I71= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV99405377; called by muse, mutect2
- NME3 | c.10C>T p.L4= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1419542037; called by muse, mutect2
- NOVA1 | c.1260C>A p.S420= | Silent (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- NPDC1 | c.501G>A p.P167= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs537671970; called by muse, mutect2
- NPY2R | c.891C>A p.V297= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- NTRK2 | c.1282C>A p.R428= | Silent (SNP) | VAF 79/432 reads (18%) | catalogued as COSV52874136; called by muse, mutect2, varscan2
- NTRK3 | c.1443G>A p.L481= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as COSV58120404; called by muse, varscan2
- OPRM1 | c.768G>C p.L256= | Silent (SNP) | VAF 24/275 reads (9%) | called by muse, mutect2
- OR1M1 | c.21C>A p.T7= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- OR5B12 | c.153C>A p.S51= | Silent (SNP) | VAF 95/179 reads (53%) | called by muse, mutect2, varscan2
- OR6B2 | c.195C>A p.S65= | Silent (SNP) | VAF 97/297 reads (33%) | catalogued as COSV99401064; called by muse, mutect2, varscan2
- OS9 | c.285G>A p.G95= | Silent (SNP) | VAF 42/366 reads (11%) | called by muse, mutect2, varscan2
- OSBPL6 | c.1005C>T p.T335= | Silent (SNP) | VAF 46/247 reads (19%) | catalogued as rs528020763; called by muse, mutect2, varscan2
- PAX6 | c.306C>A p.I102= | Silent (SNP) | VAF 127/726 reads (17%) | called by muse, mutect2, varscan2
- PCDH15 | c.3855A>G p.V1285= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as COSV57271971; called by muse, mutect2
- PCDH7 | c.1266C>A p.R422= | Silent (SNP) | VAF 30/144 reads (21%) | called by mutect2, varscan2
- PCDHA9 | c.1428G>A p.T476= | Silent (SNP) | VAF 407/772 reads (53%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1767G>T p.V589= | Silent (SNP) | VAF 227/665 reads (34%) | called by muse, mutect2, varscan2
- PDE1C | c.1704G>A p.T568= | Silent (SNP) | VAF 65/562 reads (12%) | catalogued as rs146483489; called by muse, mutect2, varscan2
- PHKA1 | c.669G>A p.G223= | Silent (SNP) | VAF 148/228 reads (65%) | called by muse, mutect2, varscan2
- PIF1 | c.1492C>A p.R498= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV99164731; called by muse, mutect2, varscan2
- PLCE1 | c.4452G>T p.S1484= | Silent (SNP) | VAF 48/452 reads (11%) | catalogued as rs759614140, COSV53349494; called by muse, mutect2, varscan2
- PPP1R12B | c.835C>A p.R279= | Silent (SNP) | VAF 50/211 reads (24%) | catalogued as COSV100408160; called by muse, mutect2, varscan2
- PPP1R3A | c.2817T>C p.T939= | Silent (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- PRG4 | c.1272C>A p.T424= | Silent (SNP) | VAF 256/790 reads (32%) | catalogued as COSV63355787; called by muse, varscan2
- PRLHR | c.279C>T p.N93= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV53303585; called by muse, mutect2
- PROKR1 | c.51C>A p.T17= | Silent (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2
- PTCD1 | c.1623G>T p.A541= | Silent (SNP) | VAF 244/604 reads (40%) | catalogued as COSV99464024; called by muse, mutect2, varscan2
- PTPRC | c.1728T>G p.S576= | Silent (SNP) | VAF 52/360 reads (14%) | called by muse, mutect2, varscan2
- PTPRN | c.192G>T p.V64= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- RAB33A | c.549G>A p.K183= | Silent (SNP) | VAF 116/273 reads (42%) | called by muse, mutect2, varscan2
- RALGAPB | c.1974G>T p.L658= | Silent (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- RFPL4B | c.639T>A p.A213= | Silent (SNP) | VAF 53/177 reads (30%) | called by muse, mutect2, varscan2
- RNF182 | c.558G>T p.V186= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as rs762477344; called by muse, mutect2, varscan2
- RTP5 | c.9G>T p.R3= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs1464306295; called by muse, mutect2, varscan2
- RTRAF | c.576A>T p.T192= | Silent (SNP) | VAF 68/183 reads (37%) | called by muse, mutect2, varscan2
- RYR1 | c.5409G>T p.P1803= | Silent (SNP) | VAF 60/154 reads (39%) | catalogued as COSV100615392; called by muse, mutect2, varscan2
- RYR2 | c.8673C>T p.D2891= | Silent (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.9990A>T p.A3330= | Silent (SNP) | VAF 138/344 reads (40%) | called by muse, mutect2, varscan2
- SCN10A | c.5289T>A p.A1763= | Silent (SNP) | VAF 53/318 reads (17%) | called by muse, mutect2, varscan2
- SCN7A | c.1248A>G p.Q416= | Silent (SNP) | VAF 70/201 reads (35%) | catalogued as rs541206253; called by muse, mutect2, varscan2
- SEC31B | c.2199G>T p.G733= | Silent (SNP) | VAF 63/179 reads (35%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.474G>T p.T158= | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- SFXN2 | c.93G>C p.T31= | Silent (SNP) | VAF 75/201 reads (37%) | called by muse, mutect2, varscan2
- SGK2 | c.18C>T p.T6= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, varscan2
- SKOR1 | c.2847G>A p.T949= | Silent (SNP) | VAF 46/410 reads (11%) | called by muse, mutect2, varscan2
- SLC13A2 | c.1131C>T p.I377= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs147640946; called by muse, mutect2, varscan2
- SLC16A1 | c.594C>T p.I198= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs755634416, COSV63709654; called by muse, mutect2
- SLC22A16 | c.1416T>C p.I472= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- SLC24A4 | c.300C>A p.V100= | Silent (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- SLC35F6 | c.156G>T p.V52= | Silent (SNP) | VAF 46/97 reads (47%) | called by muse, varscan2
- SLC49A4 | c.99G>T p.A33= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- SMIM17 | c.81G>T p.R27= | Silent (SNP) | VAF 72/171 reads (42%) | called by muse, mutect2, varscan2
- SMPD4 | c.2520G>T p.T840= (on ENST00000409031 / NM_017951.4; = p.T811= on NM_017751.4) | Silent (SNP) | VAF 60/308 reads (19%) | catalogued as rs771096170; called by muse, mutect2, varscan2
- SNTB1 | c.1581G>T p.L527= | Silent (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- SORCS1 | c.3468G>C p.T1156= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as COSV53898554; called by muse, mutect2
- SPEG | c.1836G>A p.P612= | Silent (SNP) | VAF 7/53 reads (13%) | called by mutect2, varscan2
- STIM2 | c.1779A>T p.T593= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, varscan2
- SZT2 | c.4446G>T p.L1482= (on ENST00000634258 / NM_001365999.1; = p.L1425= on NM_015284.4) | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- TEP1 | c.1716C>T p.A572= | Silent (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- TMEM121B | c.1689G>T p.G563= | Silent (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- TMEM156 | c.114G>T p.L38= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV100756088; called by muse, varscan2
- TMTC2 | c.2313A>C p.A771= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- TNNI2 | c.30C>T p.A10= | Silent (SNP) | VAF 25/296 reads (8%) | called by muse, mutect2
- TRBV19 | c.15G>T p.V5= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- TRIO | c.6444G>T p.V2148= | Silent (SNP) | VAF 58/220 reads (26%) | called by muse, mutect2, varscan2
- TSSK1B | c.615C>A p.I205= | Silent (SNP) | VAF 73/168 reads (43%) | called by muse, mutect2, varscan2
- TTC30B | c.36G>T p.G12= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs753289891; called by muse, mutect2
- UBXN7 | c.312A>C p.A104= | Silent (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- USP19 | c.2430G>T p.R810= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as rs945253135; called by mutect2, varscan2
- VARS1 | c.2229G>T p.V743= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs55982881; called by muse, mutect2, varscan2
- VCAN | c.8616T>A p.I2872= | Silent (SNP) | VAF 81/192 reads (42%) | called by muse, mutect2, varscan2
- VPS26B | c.945G>A p.E315= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as rs1565359550; called by muse, mutect2, varscan2
- WDFY4 | c.9129G>T p.A3043= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2
- WNK2 | c.1980C>A p.P660= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1032830176; called by muse, mutect2, varscan2
- XRN2 | c.483A>T p.T161= | Silent (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2487C>A p.P829= | Silent (SNP) | VAF 348/638 reads (55%) | called by muse, mutect2, varscan2
- ZHX1 | c.2268G>T p.P756= | Silent (SNP) | VAF 30/211 reads (14%) | called by muse, mutect2, varscan2
- ZNF17 | c.1440G>T p.V480= | Silent (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- ZNF543 | c.1245G>T p.R415= | Silent (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- ZNF800 | c.1705C>T p.L569= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV56174915; called by muse, mutect2, varscan2
- ZSCAN1 | c.390G>T p.S130= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as COSV99992196; called by muse, mutect2, varscan2
- AC079612.1 | n.251C>A | RNA (SNP) | VAF 143/432 reads (33%) | called by muse, mutect2, varscan2
- AK7 | c.2134-334G>T | Intron (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846212 C>A | 5'Flank (SNP) | VAF 132/225 reads (59%) | called by muse, mutect2, varscan2
- AL590867.2 | n.93C>A | RNA (SNP) | VAF 84/380 reads (22%) | called by muse, varscan2
- ANKRD45 | c.328+810C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499899 G>C | 5'Flank (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- ARPC5 | c.*4059A>T | 3'UTR (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153905021 T>G | 5'Flank (SNP) | VAF 71/112 reads (63%) | called by muse, mutect2, varscan2
- BAGE2 | n.150G>T | RNA (SNP) | VAF 115/615 reads (19%) | catalogued as rs1484471874; called by muse, mutect2, varscan2
- BAGE2 | n.151G>T | RNA (SNP) | VAF 118/624 reads (19%) | catalogued as rs78727461; called by muse, mutect2, varscan2
- BNC2 | c.2639+5585G>T | Intron (SNP) | VAF 41/212 reads (19%) | catalogued as rs762213727, COSV101034072; called by muse, mutect2, varscan2
- BSG | c.416-56G>T | Intron (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3906T>C | Intron (SNP) | VAF 97/279 reads (35%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25691T>C | Intron (SNP) | VAF 271/930 reads (29%) | called by muse, varscan2
- CCNF | c.1219-46G>C | Intron (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- CELF4 | c.1165+13G>T | Intron (SNP) | VAF 27/156 reads (17%) | catalogued as rs768110414; called by muse, mutect2, varscan2
- CEP170B | c.*1629C>G | 3'UTR (SNP) | VAF 31/311 reads (10%) | catalogued as rs1408596384; called by muse, mutect2
- CEP170P1 | n.3761C>A | RNA (SNP) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- CFAP70 | c.3135+45C>T | Intron (SNP) | VAF 55/309 reads (18%) | catalogued as rs1334883213; called by muse, mutect2, varscan2
- CLK2P1 | n.1289C>G | RNA (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- CYP27A1 | c.646+21G>C | Intron (SNP) | VAF 66/197 reads (34%) | called by muse, mutect2, varscan2
- CYP27B1 | c.963+96C>A | Intron (SNP) | VAF 140/415 reads (34%) | called by muse, mutect2, varscan2
- CYYR1 | c.-182A>C | 5'UTR (SNP) | VAF 18/84 reads (21%) | called by muse, varscan2
- CYYR1 | c.-268G>T | 5'UTR (SNP) | VAF 38/131 reads (29%) | called by muse, varscan2
- DCHS2 | n.6962T>C | RNA (SNP) | VAF 14/144 reads (10%) | catalogued as rs1488010712; called by muse, mutect2
- DDHD1 | chr14:53152765 ins GCCGCA | 5'Flank (INS) | VAF 29/105 reads (28%) | called by mutect2, varscan2
- DDX23 | c.*105G>T | 3'UTR (SNP) | VAF 96/319 reads (30%) | catalogued as rs746883566; called by muse, mutect2, varscan2
- DDX23 | c.*104G>T | 3'UTR (SNP) | VAF 100/326 reads (31%) | catalogued as rs1474316052; called by muse, mutect2, varscan2
- DGKZ | c.-4_-1dup | 5'UTR (INS) | VAF 11/46 reads (24%) | called by mutect2, varscan2
- DHRS2 | c.731+51G>A | Intron (SNP) | VAF 97/205 reads (47%) | called by muse, mutect2, varscan2
- EML5 | c.1826-260A>G | Intron (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- EYS | c.1767-6711G>C | Intron (SNP) | VAF 67/528 reads (13%) | called by muse, mutect2, varscan2
- FAM227B | c.1013-24867G>T | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1437098001; called by muse, mutect2, varscan2
- FCRL5 | c.1681+345G>C | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- FDFT1 | chr8:11802480 G>A | 5'Flank (SNP) | VAF 59/123 reads (48%) | catalogued as rs1258987104; called by muse, mutect2, varscan2
- FGD4 | c.2043+51del | Intron (DEL) | VAF 14/98 reads (14%) | catalogued as COSV56780903; called by mutect2, pindel, varscan2
- GM2A | c.426+34G>C | Intron (SNP) | VAF 99/227 reads (44%) | called by muse, mutect2, varscan2
- GPSM1 | chr9:136327244 G>T | 5'Flank (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- HMGA2 | c.*33C>A | 3'UTR (SNP) | VAF 25/182 reads (14%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899508 G>C | 3'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- KANK2 | c.-9G>T | 5'UTR (SNP) | VAF 49/118 reads (42%) | catalogued as COSV99626241; called by muse, mutect2, varscan2
- KIR3DX1 | n.515G>T | RNA (SNP) | VAF 26/422 reads (6%) | called by muse, mutect2
- KRT7 | chr12:52252297 G>A | 3'Flank (SNP) | VAF 95/475 reads (20%) | catalogued as rs1453099981; called by muse, mutect2, varscan2
- LHX9 | chr1:197912535 C>T | 5'Flank (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- LIMS1 | c.-4-4524T>G | Intron (SNP) | VAF 31/172 reads (18%) | called by mutect2, varscan2
- LINC00518 | n.903C>A | RNA (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- LINC00910 | chr17:43381292 T>A | 3'Flank (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- LINC01164 | n.659C>A | RNA (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- LINC01630 | n.1317G>T | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- MIR487B | n.54C>A | RNA (SNP) | VAF 60/213 reads (28%) | called by muse, mutect2, varscan2
- MIR646 | n.85G>T | RNA (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
53 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 53 other) are not listed here.
